Somatic mutation profile of tumor specimen TCGA-2G-AAEX-01A (aliquot TCGA-2G-AAEX-01A-11D-A42Y-10) from TCGA case TCGA-2G-AAEX, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IS; Age at diagnosis: 38.2 years (13,964 days).
Specimen TCGA-2G-AAEX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e14ffd26-b6b7-4034-95e7-c5435ead88d3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2G-AAEX-10A (Blood Derived Normal), aliquot TCGA-2G-AAEX-10A-01D-A433-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2e2a0c8f-1b9e-4c05-b1d4-eacc151328d1

The open-access MAF lists 24 somatic variants for this specimen: 17 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 5, Frame Shift Del 2, Intron 1, 5'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 48/435 reads (11%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- COL6A5 | c.2621G>C p.R874T | Missense Mutation (SNP) | VAF 85/452 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV99592658; called by muse, mutect2, varscan2
- HMMR | c.1504G>A p.E502K | Missense Mutation (SNP) | VAF 60/294 reads (20%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.689); catalogued as rs1459206064, COSV100701064; called by muse, mutect2, varscan2
- LAMA5 | c.5759C>T p.P1920L | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.912); catalogued as rs1430965522; called by muse, mutect2, varscan2
- SCRN1 | c.194C>T p.T65I | Missense Mutation (SNP) | VAF 19/146 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs758770544; called by muse, mutect2, varscan2
- TTN | c.14186T>C p.V4729A (on ENST00000591111; = p.V3802A on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/230 reads (13%) | PolyPhen benign (0.337); catalogued as COSV59998951, COSV60156629; called by muse, mutect2, varscan2
- ACLY | c.2867C>T p.P956L | Missense Mutation (SNP) | VAF 26/146 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- CACNA1C | c.3829-2A>C p.X1277_splice | Splice Site (SNP) | VAF 38/267 reads (14%) | called by muse, mutect2, varscan2
- CFAP221 | c.1002G>T p.L334F | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- FAT3 | c.10434T>A p.N3478K | Missense Mutation (SNP) | VAF 30/145 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GCN1 | c.582G>T p.Q194H | Missense Mutation (SNP) | VAF 42/220 reads (19%) | SIFT tolerated (0.56); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MUC16 | c.33160A>G p.S11054G | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); called by muse, mutect2
- NDC1 | c.999G>C p.Q333H | Missense Mutation (SNP) | VAF 53/273 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OBSCN | c.19589_19599del p.Q6530Pfs*59 | Frame Shift Del (DEL) | VAF 16/184 reads (9%) | called by mutect2, pindel
- POPDC2 | c.472T>G p.S158A | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RBBP6 | c.594del p.F198Lfs*2 | Frame Shift Del (DEL) | VAF 8/71 reads (11%) | called by mutect2, pindel, varscan2
- STAU1 | c.75G>C p.Q25H | Missense Mutation (SNP) | VAF 25/130 reads (19%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- FOXQ1 | c.462C>G p.P154= | Silent (SNP) | VAF 15/96 reads (16%) | called by muse, mutect2, varscan2
- KAT8 | c.15A>G p.G5= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as rs1473381965; called by muse, mutect2, varscan2
- KCNT1 | c.1572G>A p.Q524= (on ENST00000488444; = p.Q543= on NM_020822.3) | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as rs1378566351; called by muse, mutect2, varscan2
- PNPLA7 | c.2265C>T p.S755= | Silent (SNP) | VAF 10/80 reads (13%) | catalogued as rs756565279, COSV99480132; called by muse, mutect2, varscan2
- UTP18 | c.246G>A p.E82= | Silent (SNP) | VAF 27/160 reads (17%) | catalogued as rs779484174; called by muse, mutect2, varscan2
- MDFIC | c.-239G>T | 5'UTR (SNP) | VAF 4/37 reads (11%) | called by muse, varscan2
- MUCL3 | c.947-677A>G | Intron (SNP) | VAF 13/65 reads (20%) | called by muse, mutect2, varscan2
